Somatic mutation profile of tumor specimen TCGA-CG-5734-01A (aliquot TCGA-CG-5734-01A-11D-1600-08) from TCGA case TCGA-CG-5734, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.7 years (25,079 days).
Specimen TCGA-CG-5734-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9ddd2e0-596a-4368-856b-7d7c539c728b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5734-11A (Solid Tissue Normal), aliquot TCGA-CG-5734-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64fb9437-abf2-45a9-9a27-2b45f99f1c81

The open-access MAF lists 75 somatic variants for this specimen: 60 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, Nonsense Mutation 4, Frame Shift Del 2, Splice Site 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.58del p.S20Qfs*24 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | catalogued as rs1131691018; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC4 | c.943T>A p.C315S | Missense Mutation (SNP) | VAF 36/446 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV65316281; called by muse, mutect2
- ADAM10 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV53050211, COSV53053502; called by muse, mutect2
- ADAMTS8 | c.2068A>G p.R690G | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV57295718; called by muse, mutect2, varscan2
- AGR3 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1482876100, COSV60038950; called by muse, mutect2, varscan2
- ANKRD17 | c.5432G>A p.S1811N | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs959040754, COSV58225158; called by muse, mutect2
- AP3M2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV51529966; called by muse, mutect2
- ARV1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV59618427; called by muse, mutect2
- ASTN2 | c.3240T>A p.S1080R (on ENST00000313400 / NM_001365069.1; = p.S1029R on NM_014010.5) | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780885904, COSV56010849; called by muse, mutect2, varscan2
- BDP1 | c.882T>A p.F294L | Missense Mutation (SNP) | VAF 54/405 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62433173; called by muse, mutect2, varscan2
- CLCN5 | c.1660C>T p.R554W | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV56584309; called by muse, mutect2, varscan2
- CNTN4 | c.2769A>C p.Q923H | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV61876486; called by muse, mutect2
- CNTN5 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs779028608, COSV54338052; called by muse, mutect2
- COL14A1 | c.1397T>C p.V466A | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.306); catalogued as COSV52862832; called by muse, mutect2
- COL28A1 | c.2159T>A p.F720Y | Missense Mutation (SNP) | VAF 24/346 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.087); catalogued as COSV68083626; called by muse, mutect2
- CSMD3 | c.10307A>G p.Y3436C (on ENST00000297405 / NM_001363185.1; = p.Y3267C on NM_052900.3) | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754532783, COSV52130858; called by muse, mutect2
- DCSTAMP | c.1411T>C p.*471Rext*18 | Nonstop Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as rs371947817; called by muse, mutect2, varscan2
- DYNC1LI2 | c.1339C>T p.P447S | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.953); catalogued as rs768894802, COSV50755654; called by muse, mutect2
- EP400 | c.3560G>A p.R1187H | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.503); catalogued as rs773523648, COSV57762375; called by muse, mutect2, varscan2
- FLG | c.1708C>A p.Q570K | Missense Mutation (SNP) | VAF 220/1072 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs192402912, CM147320, COSV64245484; called by muse, varscan2
- FRMPD2 | c.1601A>C p.K534T | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV59721435; called by muse, mutect2, varscan2
- GNGT1 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 9/120 reads (8%) | catalogued as COSV50353167; called by muse, mutect2
- GRID1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as rs148165863; called by mutect2, varscan2
- HCLS1 | c.1454T>C p.L485P | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57526163; called by muse, mutect2
- HP1BP3 | c.1099T>C p.Y367H | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV56563842; called by muse, mutect2, varscan2
- ITGA3 | c.2285C>T p.T762I | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV50327284; called by muse, mutect2
- KBTBD2 | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 22/165 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58363356; called by muse, mutect2, varscan2
- KCNA6 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.01); catalogued as COSV54976647, COSV54976809; called by muse, mutect2, varscan2
- KCNU1 | c.1132A>C p.T378P | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV101299432; called by muse, mutect2, varscan2
- MROH9 | c.1601G>T p.S534I | Missense Mutation (SNP) | VAF 21/341 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV63012561; called by muse, mutect2
- MS4A13 | c.116T>A p.L39* | Nonsense Mutation (SNP) | VAF 9/118 reads (8%) | catalogued as COSV65445997; called by muse, mutect2
- MUC16 | c.34017G>T p.E11339D | Missense Mutation (SNP) | VAF 32/279 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.019); catalogued as COSV67481370; called by muse, mutect2, varscan2
- MYH10 | c.4795C>T p.R1599W | Missense Mutation (SNP) | VAF 45/335 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs760846004, COSV52606236; called by muse, mutect2, varscan2
- NIT2 | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 11/145 reads (8%) | catalogued as COSV67630615; called by muse, mutect2
- NOMO1 | c.2585C>T p.A862V | Missense Mutation (SNP) | VAF 44/668 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.59); catalogued as rs200199653, COSV55060355; called by muse, mutect2
- OR12D3 | c.178T>G p.F60V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65829416; called by muse, mutect2
- OR4L1 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs764455064, COSV59849706; called by muse, mutect2
- OR6X1 | c.317G>A p.G106D | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60009680, COSV60010222; called by muse, mutect2
- PCDHB6 | c.2087C>T p.S696L | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as rs201140097, COSV50691152; called by muse, mutect2
- PIK3CD | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as rs761349863, COSV63130537; called by muse, mutect2, varscan2
- POGLUT2 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 34/368 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.084); catalogued as COSV65683430; called by muse, mutect2
- PRAMEF6 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs756266940, COSV61910149; called by muse, mutect2
- PREX2 | c.3505G>T p.V1169L | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV55789448, COSV55795658; called by muse, mutect2
- PRKCE | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60325511; called by muse, mutect2
- PYCARD | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200845395, COSV56008543; called by muse, mutect2, varscan2
- RNF43 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV101348492; called by muse, mutect2
- RP1L1 | c.3395T>C p.L1132P | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1156774347, COSV66758295; called by mutect2, varscan2
- RTL3 | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as COSV58185105; called by muse, mutect2
- SETX | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 15/179 reads (8%) | catalogued as COSV56390571; called by muse, mutect2
- SIK3 | c.3921T>A p.D1307E (on ENST00000445177 / NM_001366686.2; = p.D1265E on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV52612624, COSV52620109; called by muse, mutect2, varscan2
- SLX4 | c.4249A>G p.S1417G | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV53566668; called by muse, mutect2
- SND1 | c.2304+1G>A p.X768_splice | Splice Site (SNP) | VAF 18/123 reads (15%) | catalogued as rs1283029806, COSV61236891; called by muse, mutect2, varscan2
- TADA3 | c.184C>G p.R62G | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs980537171, COSV55029189; called by muse, mutect2, varscan2
- TMEM106C | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 75/480 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.061); catalogued as COSV56743237; called by muse, mutect2, varscan2
- TNFRSF19 | c.343G>A p.G115R | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs781557698, COSV50312663; called by muse, mutect2, varscan2
- UNC5A | c.1528G>A p.V510I | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.6); catalogued as rs781282336, COSV52839383; called by muse, mutect2, varscan2
- ZNF823 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs746116922, COSV57875155; called by muse, mutect2, varscan2
- PCDH1 | c.1100del p.K367Rfs*9 | Frame Shift Del (DEL) | VAF 28/189 reads (15%) | called by mutect2, pindel, varscan2
- PCMTD1 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- PCMTD1 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BRWD3 | c.5379G>A p.R1793= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV64751808; called by muse, mutect2
- CNR1 | c.651C>T p.S217= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as rs762988417, COSV62990194; called by mutect2, varscan2
- G6PD | c.1269C>T p.T423= | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as COSV63703923; called by muse, mutect2, varscan2
- GJA8 | c.999C>T p.G333= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs782035866, COSV53789826; called by muse, mutect2, varscan2
- GPBAR1 | c.933C>T p.P311= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs1419511835, COSV50308859; called by muse, mutect2, varscan2
- GRIK1 | c.1011G>A p.R337= | Silent (SNP) | VAF 11/106 reads (10%) | catalogued as COSV58726774; called by muse, mutect2, varscan2
- KIF15 | c.3192C>T p.D1064= | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV58163493; called by muse, mutect2
- LRRC4B | c.1194G>A p.T398= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs1325695952, COSV100976040, COSV65350505; called by muse, mutect2, varscan2
- PAPPA2 | c.759C>A p.T253= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV62783069; called by muse, mutect2, varscan2
- PCDH1 | c.2013G>A p.L671= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as COSV54617496, COSV99746622; called by muse, varscan2
- PCDHA4 | c.1521C>T p.Y507= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs1212194365, COSV63541674; called by muse, mutect2, varscan2
- RAB38 | c.285A>G p.P95= | Silent (SNP) | VAF 67/479 reads (14%) | catalogued as COSV54714573; called by muse, varscan2
- SLIT2 | c.1674T>C p.P558= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV56586014; called by muse, mutect2, varscan2
- ZNF142 | c.3714C>G p.L1238= (on ENST00000411696 / NM_001379660.1; = p.L1038= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as rs750542635, COSV68744840; called by muse, mutect2
- RBFOX1 | c.28-185137G>A | Intron (SNP) | VAF 24/326 reads (7%) | catalogued as rs771567004, COSV60946776, COSV60951877; called by muse, mutect2
